Somatic mutation profile of tumor specimen MMRF_1911_1_BM_CD138pos (aliquot MMRF_1911_1_BM_CD138pos_T1_KBS5U_L07245) from MMRF case MMRF_1911, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 53.9 years (19,703 days).
Specimen MMRF_1911_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 65d6dbd8-f4ef-4698-8073-ed7203be8f2c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1911_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1911_1_PB_Whole_C3_KBS5U_L07246; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bd96c94e-e06a-4927-ba6a-632572a4dffb

The open-access MAF lists 99 somatic variants for this specimen: 38 protein-altering or splice-affecting, 10 silent, 51 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, 3'UTR 27, Intron 15, Silent 10, 5'UTR 5, 3'Flank 2, Frame Shift Del 2, Nonsense Mutation 2, 5'Flank 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- NRAS | c.37G>C p.G13R | Missense Mutation (SNP) | VAF 128/552 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs121434595, COSV54736386, COSV54736476, COSV54736550; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- B3GAT1 | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as rs1194822057, COSV56999766; called by muse, mutect2, varscan2
- COL6A1 | c.1597G>A p.A533T | Missense Mutation (SNP) | VAF 55/103 reads (53%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs546480880, COSV62612479; called by muse, mutect2, varscan2
- GNAS | c.1535G>A p.R512Q | Missense Mutation (SNP) | VAF 58/99 reads (59%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.012); catalogued as rs751912596, COSV100005617; called by muse, mutect2, varscan2
- IGLV3-1 | c.251A>G p.N84S | Missense Mutation (SNP) | VAF 72/76 reads (95%) | SIFT tolerated (0.45); PolyPhen benign (0.01); catalogued as rs373605544; called by muse, mutect2, varscan2
- LGALS4 | c.520C>G p.Q174E | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs1415376979; called by muse, mutect2, varscan2
- NECAB1 | c.1010C>T p.T337I | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV101341091, COSV70243676; called by muse, mutect2, varscan2
- SLC35B1 | c.53C>T p.P18L | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.856); catalogued as rs1442168636; called by muse, mutect2, varscan2
- ZBBX | c.688G>T p.V230L | Missense Mutation (SNP) | VAF 44/145 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as COSV56786731; called by muse, mutect2, varscan2
- ARID4A | c.2498_2505delinsAAC p.L833* | Nonsense Mutation (DEL) | VAF 14/66 reads (21%) | called by pindel, varscan2*
- ATPAF1 | c.956T>C p.L319P (on ENST00000574428; = p.L342P on NM_022745.4) | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- CAPN5 | c.1463G>A p.S488N (on ENST00000456580; = p.S448N on NM_004055.5) | Missense Mutation (SNP) | VAF 126/263 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- CDC73 | c.1072C>G p.R358G | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- CSMD3 | c.4979A>G p.D1660G (on ENST00000297405 / NM_001363185.1; = p.D1556G on NM_052900.3) | Missense Mutation (SNP) | VAF 127/263 reads (48%) | SIFT tolerated (1); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CWF19L2 | c.1765A>G p.R589G | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- DNAAF3 | c.751C>T p.P251S (on ENST00000524407 / NM_001256715.2; = p.P298S on NM_178837.4) | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- FSIP2 | c.17651T>C p.I5884T | Missense Mutation (SNP) | VAF 70/157 reads (45%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- GUCY2F | c.1049G>T p.G350V | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- PALM | c.28T>C p.S10P | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- PAN3 | c.1746_1750del p.H582Qfs*2 | Frame Shift Del (DEL) | VAF 16/47 reads (34%) | called by mutect2, pindel, varscan2
- PCDH15 | c.2949A>C p.E983D | Missense Mutation (SNP) | VAF 49/171 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- PGAM2 | c.20T>C p.V7A | Missense Mutation (SNP) | VAF 83/168 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PPARA | c.215T>G p.L72R | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- PPFIA1 | c.2270G>C p.G757A | Missense Mutation (SNP) | VAF 49/219 reads (22%) | SIFT tolerated (0.83); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RASSF2 | c.151A>T p.I51F | Missense Mutation (SNP) | VAF 32/137 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- SLC39A6 | c.316T>A p.S106T | Missense Mutation (SNP) | VAF 19/273 reads (7%) | SIFT tolerated (0.69); PolyPhen benign (0.021); called by muse, mutect2
- SLFN14 | c.2354C>A p.T785K | Missense Mutation (SNP) | VAF 47/157 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- SMAD5 | c.1150A>T p.N384Y | Missense Mutation (SNP) | VAF 59/249 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- STXBP5 | c.2666A>T p.E889V (on ENST00000321680 / NM_001127715.2; = p.E853V on NM_139244.4) | Missense Mutation (SNP) | VAF 60/301 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- TDGF1 | c.89G>A p.G30E | Missense Mutation (SNP) | VAF 7/171 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); called by muse, mutect2
- TDRD15 | c.5720T>C p.V1907A | Missense Mutation (SNP) | VAF 94/181 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- TRAF3 | c.297+2T>A p.X99_splice | Splice Site (SNP) | VAF 10/140 reads (7%) | called by muse, mutect2
- TTC16 | c.1501G>C p.A501P | Missense Mutation (SNP) | VAF 38/77 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- YTHDC1 | c.551A>C p.E184A | Missense Mutation (SNP) | VAF 14/185 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.012); called by muse, mutect2
- ZHX2 | c.2171del p.G724Vfs*23 | Frame Shift Del (DEL) | VAF 90/212 reads (42%) | called by mutect2, pindel, varscan2
- ZNF559 | c.997G>T p.A333S | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.612); called by muse, mutect2, varscan2
- ZNF605 | c.59_60insA p.W20* | Nonsense Mutation (INS) | VAF 58/171 reads (34%) | called by mutect2, pindel, varscan2
- ACSL6 | c.405C>T p.S135= (on ENST00000379240; = p.S160= on NM_015256.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 17/94 reads (18%) | catalogued as rs771369534, COSV57305526; called by muse, mutect2, varscan2
- DNTTIP2 | c.1506T>C p.N502= | Silent (SNP) | VAF 191/403 reads (47%) | called by muse, mutect2, varscan2
- IGLV3-1 | c.78A>G p.P26= | Silent (SNP) | VAF 52/52 reads (100%) | catalogued as rs570281801; called by muse, varscan2
- LRRC14B | c.465C>T p.P155= | Silent (SNP) | VAF 17/37 reads (46%) | catalogued as rs1384422300; called by muse, mutect2, varscan2
- NPTX1 | c.175C>T p.L59= | Silent (SNP) | VAF 6/72 reads (8%) | catalogued as rs1411449862; called by muse, mutect2
- RABGAP1 | c.312C>T p.S104= | Silent (SNP) | VAF 132/279 reads (47%) | catalogued as COSV100438562; called by muse, mutect2, varscan2
- SLC41A2 | c.1044T>C p.I348= | Silent (SNP) | VAF 16/84 reads (19%) | called by muse, mutect2, varscan2
- SOX2 | c.267G>A p.P89= | Silent (SNP) | VAF 85/166 reads (51%) | catalogued as COSV57622067; called by muse, mutect2, varscan2
- TENT4B | c.282C>T p.H94= (on ENST00000561678 / NM_001365323.2; = p.H79= on NM_001040284.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 154/341 reads (45%) | catalogued as rs1392736866; called by muse, mutect2, varscan2
- TGM1 | c.684A>T p.S228= | Silent (SNP) | VAF 175/188 reads (93%) | called by muse, mutect2, varscan2
- BICRAL | c.*1351C>T | 3'UTR (SNP) | VAF 22/560 reads (4%) | catalogued as rs1400548575; called by muse, mutect2
- BTG2 | c.*1015T>G | 3'UTR (SNP) | VAF 10/158 reads (6%) | called by muse, mutect2
- BUB3 | c.*1098G>T | 3'UTR (SNP) | VAF 104/209 reads (50%) | catalogued as rs1196387197; called by muse, mutect2, varscan2
- CA12 | c.*4116G>A | 3'UTR (SNP) | VAF 44/71 reads (62%) | catalogued as rs1250120831; called by muse, mutect2, varscan2
- CAPSL | c.525+20C>A | Intron (SNP) | VAF 43/419 reads (10%) | called by muse, mutect2
- CCSER2 | c.*2620G>T | 3'UTR (SNP) | VAF 75/150 reads (50%) | called by muse, mutect2, varscan2
- CDH19 | c.*3001T>G | 3'UTR (SNP) | VAF 59/99 reads (60%) | called by muse, mutect2, varscan2
- CDH23 | c.3369+3683C>A | Intron (SNP) | VAF 41/104 reads (39%) | catalogued as COSV56467837; called by muse, mutect2, varscan2
- CUL3 | c.*4095A>T | 3'UTR (SNP) | VAF 4/85 reads (5%) | called by muse, mutect2
- DCDC2 | c.*2396T>G | 3'UTR (SNP) | VAF 37/85 reads (44%) | called by muse, mutect2, varscan2
- DDX3Y | c.*268T>G | 3'UTR (SNP) | VAF 40/42 reads (95%) | called by muse, mutect2, varscan2
- ELOVL6 | c.-185C>G | 5'UTR (SNP) | VAF 102/184 reads (55%) | called by muse, mutect2, varscan2
- FBXO21 | chr12:117144624 A>G | 3'Flank (SNP) | VAF 14/149 reads (9%) | called by muse, mutect2
- FBXO24 | c.-36C>G | 5'UTR (SNP) | VAF 118/273 reads (43%) | called by muse, mutect2, varscan2
- FHAD1 | c.1474-126G>T | Intron (SNP) | VAF 20/33 reads (61%) | called by muse, varscan2
- GALNT9 | c.*417C>G | 3'UTR (SNP) | VAF 50/94 reads (53%) | called by muse, mutect2, varscan2
- GLCCI1 | c.*211A>T | 3'UTR (SNP) | VAF 36/131 reads (27%) | called by muse, mutect2, varscan2
- IGSF9 | c.-125G>A | 5'UTR (SNP) | VAF 30/110 reads (27%) | called by muse, mutect2, varscan2
- IRX3 | c.*173C>A | 3'UTR (SNP) | VAF 35/173 reads (20%) | catalogued as rs374787817; called by muse, mutect2, varscan2
- ISOC1 | c.*30T>C | 3'UTR (SNP) | VAF 38/81 reads (47%) | called by muse, mutect2, varscan2
- KYAT1 | c.1122+87A>T | Intron (SNP) | VAF 34/63 reads (54%) | called by muse, mutect2, varscan2
- LINC00305 | n.910C>A | RNA (SNP) | VAF 44/189 reads (23%) | called by muse, mutect2, varscan2
- LONRF2 | c.*173G>A | 3'UTR (SNP) | VAF 7/170 reads (4%) | called by muse, mutect2
- LPP | c.*3144A>G | 3'UTR (SNP) | VAF 6/39 reads (15%) | called by muse, mutect2, varscan2
- LRRC2 | chr3:46516979 C>T | 3'Flank (SNP) | VAF 31/71 reads (44%) | catalogued as rs967219805; called by muse, mutect2, varscan2
- MBD2 | c.542+1664G>A | Intron (SNP) | VAF 9/53 reads (17%) | called by muse, mutect2
- MDGA1 | c.*5336G>A | 3'UTR (SNP) | VAF 57/236 reads (24%) | catalogued as rs1417576186; called by muse, mutect2, varscan2
- METAP1D | c.*1377G>A | 3'UTR (SNP) | VAF 55/90 reads (61%) | called by muse, mutect2, varscan2
- OR2H1 | c.*13+204T>G | Intron (SNP) | VAF 23/198 reads (12%) | called by muse, mutect2, varscan2
- PAPPA2 | c.-858G>T | 5'UTR (SNP) | VAF 35/64 reads (55%) | called by muse, mutect2, varscan2
- PAX6 | c.11-201G>A | Intron (SNP) | VAF 45/195 reads (23%) | catalogued as rs1351294715; called by muse, mutect2, varscan2
- PPAN | c.822+18G>T | Intron (SNP) | VAF 6/142 reads (4%) | called by muse, mutect2
- PPARGC1A | c.234+1732C>A | Intron (SNP) | VAF 6/70 reads (9%) | called by muse, mutect2
- PPP2R5C | c.93+3135C>G | Intron (SNP) | VAF 20/55 reads (36%) | called by muse, mutect2, varscan2
- PPP4R1 | c.2547+87T>C | Intron (SNP) | VAF 5/59 reads (8%) | called by muse, mutect2
- PTBP2 | chr1:96721739 G>T | 5'Flank (SNP) | VAF 6/80 reads (8%) | called by muse, mutect2
- PTPRN2 | c.2783+2261G>T | Intron (SNP) | VAF 6/90 reads (7%) | called by muse, mutect2
- RAB24 | chr5:177303709 del GGGGGCTAGAGG | 5'UTR (DEL) | VAF 9/37 reads (24%) | called by mutect2, pindel, varscan2
- RNF168 | c.*1105A>C | 3'UTR (SNP) | VAF 185/722 reads (26%) | called by muse, mutect2, varscan2
- S1PR3 | c.*2133T>G | 3'UTR (SNP) | VAF 63/124 reads (51%) | called by muse, mutect2, varscan2
- SETX | c.*429_*432del | 3'UTR (DEL) | VAF 5/60 reads (8%) | called by mutect2, pindel
- STEAP3 | c.-77+6769G>A | Intron (SNP) | VAF 82/158 reads (52%) | called by muse, mutect2, varscan2
- STK32A | c.*764T>C | 3'UTR (SNP) | VAF 11/39 reads (28%) | called by muse, mutect2, varscan2
- STPG2 | c.*2885T>C | 3'UTR (SNP) | VAF 64/142 reads (45%) | catalogued as rs1170922868; called by muse, mutect2, varscan2
- STXBP6 | c.155-21609G>C | Intron (SNP) | VAF 4/45 reads (9%) | called by muse, mutect2
- TFDP3 | c.*266T>C | 3'UTR (SNP) | VAF 144/293 reads (49%) | called by muse, mutect2, varscan2
- TMEM132B | c.*7174T>A | 3'UTR (SNP) | VAF 9/98 reads (9%) | called by muse, mutect2
- TSHZ1 | c.*1123A>G | 3'UTR (SNP) | VAF 5/107 reads (5%) | called by muse, mutect2
- TTC32 | c.149+419G>C | Intron (SNP) | VAF 10/116 reads (9%) | called by muse, mutect2
- WDR72 | c.*3257A>G | 3'UTR (SNP) | VAF 22/145 reads (15%) | called by muse, mutect2, varscan2
- ZNF462 | c.*2533T>C | 3'UTR (SNP) | VAF 16/52 reads (31%) | called by muse, mutect2, varscan2
